Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A5RH, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A5RH-01A (Primary Tumor).

[page 1 of 5]
Gender
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Order Number

Results

Final

Source of Specimen

- A. LEFT DISTAL URETER MARGIN INKED FS-
- B. RIGHT DISTAL URETER MARGIN INKED FS-
- C. BLADDER, PROSTATE-
- D. LEFT PELVIC LYMPH NODES-
- E. RIGHT PELVIC LYMPH NODES-

ICD-0-3
carcinoma, urothelial, NOS 8/20/3
Site= bladder, trigone c67.0

fw
2/17/13

FINAL DIAGNOSIS:

- A. LEFT DISTAL URETER MARGIN INKED FS-
NO CARCINOMA SEEN.
- B. RIGHT DISTAL URETER MARGIN INKED FS-
NO CARCINOMA SEEN.
- C. BLADDER, PROSTATE-
INVASIVE CARCINOMA, HIGH GRADE.

TUMOR SITE: RIGHT AND LEFT TRIGONE, URINARY BLADDER.

HISTOLOGIC TYPE: UROTHELIAL WITH FOCAL SARCOMATOID (SPINDLE CELL) PATTERN.

SQUAMOUS DIFFERENTIATION: NOT PRESENT.

GLANDULAR DIFFERENTIATION: NOT PRESENT.

TUMOR SIZE: 7 CM.

HISTOLOGIC GRADE: 3/3.

EXTRAVESICULAR MASS: MICROSCOPICALLY PRESENT.

Prepared f

[page 2 of 5]
SPECIMEN TYPE: RADICAL CYSTOPROSTATECTOMY

TNM STAGE: pT3a, pN0, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 9

LYMPHATIC (SMALL VESSEL) INVASION: SEEN.

BLOOD VESSEL INVASION: SEEN.

ASSOCIATED EPITHELIAL LESIONS: IN SITU UROTHELIAL CARCINOMA
IDENTIFIED.

NO TUMOR SEEN AT MARGINS.

PROSTATIC HYPERPLASIA.

D. LEFT PELVIC LYMPH NODES-
NO CARCINOMA SEEN IN FIVE LYMPH NODES (0/5).

E. RIGHT PELVIC LYMPH NODES-
NO CARCINOMA SEEN IN FOUR LYMPH NODES (0/4).

Signed Others

Frozen Section

A. LEFT DISTAL URETER, MARGIN INKED: NO CARCINOMA SEEN.

Case Clinical Information

BLADDER CANCER, PANCREATIC MASS

Gross Description

A. Received in formalin labeled with the patient's name and
"left distal ureter margin FS" is a gray-tan frozen section
tissue fragment measuring 0.7 x 0.5 cm. Wrapped and entirely
submitted in A1.

B. Received in formalin labeled with the patient's name and
"right distal ureter margin FS" is a gray-tan frozen section

Prepared for

[page 3 of 5]
tissue fragment measuring 0.9 x 0.5 cm. Wrapped and submitted in B1.

C. Received in formalin labeled with the patient's name and "bladder and prostate" is a bladder with attached prostate with an overall dimension of 15 x 14 x 8 cm. The bladder measures 7 x 5 x 6.5 cm. The right seminal vesicle is 3 x 1.5 cm. The right vas is 6 x 0.4 cm. The left seminal vesicle is 3 x 1.5 cm and the left vas is 5 x 0.4 cm. The stump of the right ureter is 1 x 0.5 cm. The stump of the left ureter is 1 x 0.5 cm. The right side of the prostate has been previously inked in blue, left side of the prostate has been previously inked in black. The prostatic apical margin is shaved and the specimen has been previously opened anteriorly prior to fixation. The bladder has gray-tan mucosa and is remarkable for a gray-brown, friable, necrotic mass involving the entire bladder and measuring 7 x 5.5 x 5 cm. Sectioning through the tumor appears to involve the muscularis and no lymph nodes were grossly identified. The specimen is represented as follows: the distal urethral margin=C1; right trigone=C2-C3; anterior wall=C4; lateral wall=C5; posterior wall=C6; dome=C7; left trigone=C8-C10; left lateral wall=C11-C13; left posterior wall=C14-C19; right prostate from apex to base=C20-C21; right seminal vesicle and vas deferens =C22; left prostate from apex to base=C23-C24; left seminal vesicle and vas deferens=C25.

D. Received in formalin labeled with the patient's name and "left pelvic lymph nodes" consist of yellow-tan, fibroadipose tissues measuring 4.5 x 4 x 4 cm. Five lymph nodes are grossly identified. The largest measures 2 x 1 cm and the smallest measures 0.9 x 0.4 cm. The specimen is submitted as follows: one lymph node bisected=D1; one lymph node bisected=D2; one lymph node bisected=D3; one lymph node bisected=D4; one lymph node bisected=D5.

E. Received in formalin labeled with the patient's name and "right pelvic lymph node" is yellow-tan, fibroadipose tissue measuring 4.5 x 4 x 2.5 cm. Four lymph nodes are grossly identified. The largest measures 1.7 x 1 cm and the smallest measures 1 x 1 cm. Submitted as follows: one lymph node bisected=E1; one lymph node bisected=E2; one lymph node bisected=E3; and one lymph node serially sectioned and entirely submitted=E4-E5.;

Procedure

A. AA ROUTINE H&E X1 BLOCK
H&E X1

Prepared for

[page 4 of 5]
B. AA ROUTINE H&E X1 BLOCK
H&E X1

C. AA ROUTINE H&E X1 BLOCK.1
H&E X1 A RECUTS

C. AA ROUTINE H&E X1 BLOCK.2
H&E X1

C. AA ROUTINE H&E X1 BLOCK.3
H&E X1

C. AA ROUTINE H&E X1 BLOCK.4
H&E X1

C. AA ROUTINE H&E X1 BLOCK.5
H&E X1

C. AA ROUTINE H&E X1 BLOCK.6
H&E X1

C. AA ROUTINE H&E X1 BLOCK.7
H&E X1

C. AA ROUTINE H&E X1 BLOCK.8
H&E X1

C. AA ROUTINE H&E X1 BLOCK.9
H&E X1

C. AA ROUTINE H&E X1 BLOCK.10
H&E X1

C. AA ROUTINE H&E X1 BLOCK.11
H&E X1

C. AA ROUTINE H&E X1 BLOCK.12
H&E X1

C. AA ROUTINE H&E X1 BLOCK.13
H&E X1

C. AA ROUTINE H&E X1 BLOCK.14
H&E X1

C. AA ROUTINE H&E X1 BLOCK.15
H&E X1

C. AA ROUTINE H&E X1 BLOCK.16
H&E X1

C. AA ROUTINE H&E X1 BLOCK.17
H&E X1

C. AA ROUTINE H&E X1 BLOCK.18
H&E X1

C. AA ROUTINE H&E X1 BLOCK.19
H&E X1

C. AA ROUTINE H&E X1 BLOCK.20
H&E X1

C. AA ROUTINE H&E X1 BLOCK.21
H&E X1

C. AA ROUTINE H&E X1 BLOCK.22
H&E X1

C. AA ROUTINE H&E X1 BLOCK.23
H&E X1

C. AA ROUTINE H&E X1 BLOCK.24

Prepared for

[page 5 of 5]
H&E X1
C. AA ROUTINE H&E X1 BLOCK.25
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
D. AA ROUTINE H&E X1 BLOCK.4
H&E X1
D. AA ROUTINE H&E X1 BLOCK.5
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.4
H&E X1
E. AA ROUTINE H&E X1 BLOCK.5
H&E X1

Prepared:

Handwritten notes: 12/26/13, MB, 2/5/13

Source: NCI Genomic Data Commons file 552aa1fd-a5d3-498c-8fe3-5281200f1cd2 (TCGA-K4-A5RH.60531FDD-78B7-4DAF-8B6F-ED9C4D6AA2BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).